BEATAML1.0 case 2751 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Leukemias, NOS; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/70253a52-4531-485f-bea9-a263af89459c

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Mixed phenotype acute leukemia, T/myeloid, NOS: ICD-O-3 morphology code: 9809/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 38.5 years (14,075 days); Progression or recurrence: no.

Biospecimens (1 sample)
- Sample BA3172D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
